Somatic mutation profile of tumor specimen C3N-01017-04 (aliquot CPT0069890006) from CPTAC case C3N-01017, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 56.8 years (20,756 days).
Specimen C3N-01017-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94bf7021-6d92-4d38-8eed-edc9df268e27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01017-71 (Blood Derived Normal), aliquot CPT0069980002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67a9e585-4437-41fe-945d-aa0aedf49730

The open-access MAF lists 278 somatic variants for this specimen: 190 protein-altering or splice-affecting, 59 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 166, Silent 59, Intron 17, Nonsense Mutation 13, Frame Shift Del 3, RNA 3, 5'Flank 3, Frame Shift Ins 2, 3'Flank 2, Splice Site 2, In Frame Del 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 57/216 reads (26%) | catalogued as rs869312782, COSV52692559, COSV52721885, COSV53153630, COSV53758203; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.4184C>T p.P1395L | Missense Mutation (SNP) | VAF 105/442 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1047379; called by muse, mutect2, varscan2
- AKAP17A | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.85); catalogued as rs757205201, COSV100001941; called by muse, mutect2
- APBA1 | c.629G>T p.R210L | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.072); catalogued as COSV55221782; called by muse, mutect2, varscan2
- C22orf42 | c.218del p.L73Rfs*15 | Frame Shift Del (DEL) | VAF 60/251 reads (24%) | catalogued as COSV66076003; called by mutect2, pindel, varscan2
- CCNP | c.247dup p.D83Gfs*45 | Frame Shift Ins (INS) | VAF 50/427 reads (12%) | catalogued as rs1351833679; called by mutect2, pindel, varscan2
- CD248 | c.1538A>G p.Q513R | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs1397457915, COSV60937688; called by muse, mutect2, varscan2
- CHAMP1 | c.38G>T p.R13L | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs138074590; called by muse, varscan2
- COL15A1 | c.2368G>T p.G790W | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753681922; called by muse, mutect2, varscan2
- CRAMP1 | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.75); catalogued as rs1350400126, COSV104387145; called by muse, mutect2, varscan2
- CUL3 | c.2266C>T p.R756* | Nonsense Mutation (SNP) | VAF 21/151 reads (14%) | catalogued as COSV100024294; called by muse, mutect2, varscan2
- DACT1 | c.2459A>G p.K820R | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV100242119; called by muse, mutect2
- DCHS1 | c.4553G>A p.R1518Q | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs753287108; called by muse, mutect2, varscan2
- DES | c.1201G>T p.E401* | Nonsense Mutation (SNP) | VAF 25/220 reads (11%) | catalogued as CM063950; called by muse, mutect2
- DHX9 | c.1601A>T p.Y534F | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.075); catalogued as COSV62359830; called by muse, mutect2, varscan2
- DNAH5 | c.8278A>G p.R2760G | Missense Mutation (SNP) | VAF 44/1638 reads (3%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV54208425; called by muse, mutect2
- DNAH9 | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as COSV52359825; called by muse, mutect2, varscan2
- ESR2 | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 29/197 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs528840784, COSV50828992; called by muse, mutect2, varscan2
- FAM71A | c.1523C>A p.S508Y | Missense Mutation (SNP) | VAF 147/354 reads (42%) | SIFT tolerated (1); PolyPhen possibly damaging (0.888); catalogued as COSV54237229; called by muse, mutect2, varscan2
- FBXL19 | c.1456C>T p.R486C | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.247); catalogued as rs757149177; called by muse, mutect2, varscan2
- GABRA1 | c.1105G>T p.A369S | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.189); catalogued as rs775344663, COSV50112042; called by muse, mutect2, varscan2
- GAS2L3 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs570007535; called by muse, mutect2, varscan2
- IGLV5-37 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs750927800; called by muse, mutect2, varscan2
- ITPRID1 | c.1076G>T p.G359V | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV60070161; called by muse, mutect2, varscan2
- JAG1 | c.1191G>T p.K397N | Missense Mutation (SNP) | VAF 30/409 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as CD003523; called by muse, mutect2
- KDM2A | c.3052C>G p.Q1018E | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV58190172; called by muse, mutect2, varscan2
- KIAA1549 | c.4801C>G p.P1601A | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as rs748211482, COSV54314962; called by muse, mutect2, varscan2
- LILRB5 | c.535C>A p.L179M | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs1220480803, COSV60261600; called by muse, mutect2, varscan2
- MAST1 | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1448895866, COSV52254869; called by muse, mutect2, varscan2
- MINDY1 | c.206del p.P69Lfs*20 | Frame Shift Del (DEL) | VAF 37/223 reads (17%) | catalogued as COSV56501710; called by mutect2, pindel, varscan2
- MUC16 | c.18526A>G p.T6176A | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs1282979027, COSV67444641; called by muse, mutect2, varscan2
- MUC17 | c.2347G>T p.E783* | Nonsense Mutation (SNP) | VAF 32/163 reads (20%) | catalogued as COSV60280441; called by muse, mutect2, varscan2
- MYF6 | c.191C>G p.A64G | Missense Mutation (SNP) | VAF 48/400 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as COSV57353681; called by muse, mutect2, varscan2
- MYOCD | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV58506565; called by muse, mutect2, varscan2
- NAALAD2 | c.1369A>G p.T457A | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV58963248, COSV58964158; called by muse, mutect2, varscan2
- NECTIN4 | c.1513G>T p.G505W | Missense Mutation (SNP) | VAF 144/489 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63513632; called by muse, mutect2, varscan2
- OLFM4 | c.1414C>G p.H472D | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99524191; called by muse, mutect2
- OR10H2 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 12/112 reads (11%) | catalogued as COSV59946026; called by muse, mutect2, varscan2
- OR10X1 | c.584G>T p.C195F | Missense Mutation (SNP) | VAF 51/228 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146846805, COSV100936578; called by muse, mutect2, varscan2
- OR2T2 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 46/305 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100737711; called by mutect2, varscan2
- OR4Q3 | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100056846; called by muse, mutect2, varscan2
- PCDHB11 | c.1912C>T p.H638Y | Missense Mutation (SNP) | VAF 36/840 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.236); catalogued as rs782180428; called by muse, mutect2
- PGR | c.2605C>T p.R869C | Missense Mutation (SNP) | VAF 50/347 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1181450031, COSV54810380; called by muse, mutect2, varscan2
- PPP4R3C | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.33); catalogued as rs1255970616; called by muse, mutect2, varscan2
- PRKG1 | c.214C>A p.P72T | Missense Mutation (SNP) | VAF 27/318 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs776811147, COSV64826736; called by muse, mutect2
- PROS1 | c.283G>T p.G95W | Missense Mutation (SNP) | VAF 60/576 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as CM971243, COSV100820318; called by muse, mutect2
- PSEN1 | c.944A>G p.Y315C | Missense Mutation (SNP) | VAF 48/382 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.85); catalogued as COSV56193335; called by muse, mutect2, varscan2
- PZP | c.1192C>T p.Q398* | Nonsense Mutation (SNP) | VAF 26/189 reads (14%) | catalogued as rs1237599786; called by muse, mutect2, varscan2
- RESP18 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.273); catalogued as rs1298354814; called by muse, mutect2
- RYR3 | c.12377C>T p.A4126V (on ENST00000389232; = p.A4127V on NM_001036.6) | Missense Mutation (SNP) | VAF 30/354 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.116); catalogued as rs749374315, COSV66786898; called by muse, mutect2
- SLC16A7 | c.1384G>A p.V462I | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1336676910, COSV53896099; called by muse, mutect2
- SLC17A2 | c.807G>C p.M269I | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.31); catalogued as COSV55351044; called by muse, mutect2, varscan2
- SPATA31E1 | c.497G>A p.C166Y | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770726922; called by muse, mutect2, varscan2
- SPRY3 | c.137T>C p.V46A | Missense Mutation (SNP) | VAF 31/309 reads (10%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs753172710; called by muse, mutect2, varscan2
- STXBP2 | c.869A>G p.E290G | Missense Mutation (SNP) | VAF 96/525 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs1353855735; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAAR2 | c.311C>A p.S104* (on ENST00000367931 / NM_001033080.1; = p.S59* on NM_014626.3) | Nonsense Mutation (SNP) | VAF 22/257 reads (9%) | catalogued as rs550125345, COSV51578825; called by muse, mutect2
- TDRD5 | c.1480G>C p.D494H | Missense Mutation (SNP) | VAF 53/225 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54242147; called by muse, mutect2, varscan2
- TMEM63B | c.439G>T p.D147Y | Missense Mutation (SNP) | VAF 48/222 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52477397; called by muse, mutect2, varscan2
- TNR | c.3070A>T p.T1024S | Missense Mutation (SNP) | VAF 35/267 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.209); catalogued as COSV99688726; called by muse, mutect2, varscan2
- TTN | c.64237G>A p.A21413T (on ENST00000591111; = p.A13989T on NM_003319.4) | Missense Mutation (SNP) | VAF 43/168 reads (26%) | PolyPhen benign (0.439); catalogued as COSV100601334; called by muse, mutect2, varscan2
- TTN | c.55300C>T p.P18434S (on ENST00000591111; = p.P11010S on NM_003319.4) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | PolyPhen benign (0.015); catalogued as rs376561549; called by muse, mutect2, varscan2
- UNC13C | c.2393G>A p.G798E | Missense Mutation (SNP) | VAF 41/216 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs374236768; called by muse, varscan2
- VCAN | c.1770C>G p.I590M | Missense Mutation (SNP) | VAF 73/363 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs998395916; called by muse, mutect2, varscan2
- ZGLP1 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs146292088; called by muse, mutect2, varscan2
- ZNF257 | c.620del p.G207Afs*15 | Frame Shift Del (DEL) | VAF 11/106 reads (10%) | catalogued as COSV99078255; called by mutect2, varscan2
- ZNF417 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.848); catalogued as rs778531452; called by muse, mutect2, varscan2
- ZNF426 | c.977A>G p.H326R | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs199824998; called by muse, mutect2, varscan2
- ZNF426 | c.218A>G p.E73G | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1473341766; called by muse, mutect2, varscan2
- ZNF735 | c.907G>A p.G303S | Missense Mutation (SNP) | VAF 42/237 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV70034919, COSV99068862; called by muse, mutect2, varscan2
- ADGRG4 | c.8864T>A p.F2955Y | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- AKAP9 | c.11494G>T p.E3832* (on ENST00000359028; = p.E3808* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 45/278 reads (16%) | called by muse, mutect2, varscan2
- AKNA | c.50A>G p.K17R | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ALB | c.1816G>T p.A606S | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ALG10B | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 91/553 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ARF5 | c.294G>T p.E98D | Missense Mutation (SNP) | VAF 49/280 reads (18%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARFGAP2 | c.758A>G p.K253R | Missense Mutation (SNP) | VAF 36/261 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- ARSJ | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP10A | c.4054C>A p.Q1352K | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.02); called by muse, mutect2
- BPIFA3 | c.346T>C p.S116P | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- CFAP47 | c.8645G>C p.W2882S | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COPA | c.2064G>T p.Q688H | Missense Mutation (SNP) | VAF 54/253 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- CPED1 | c.854G>C p.R285P | Missense Mutation (SNP) | VAF 34/244 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- CSMD1 | c.4795G>C p.D1599H (on ENST00000520002; = p.D1598H on NM_033225.6) | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- CXorf66 | c.1085A>T p.*362Lext*10 | Nonstop Mutation (SNP) | VAF 14/29 reads (48%) | called by muse, varscan2
- DGKI | c.2032C>G p.Q678E | Missense Mutation (SNP) | VAF 64/371 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- DNAH5 | c.13836G>T p.W4612C | Missense Mutation (SNP) | VAF 72/2160 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH7 | c.6289G>T p.G2097C | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DNAH7 | c.1044G>T p.L348F | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- DNAJB9 | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 74/410 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by mutect2, varscan2
- DNASE1L1 | c.187G>T p.G63C | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- DPP6 | c.768T>A p.F256L (on ENST00000377770 / NM_001364500.2; = p.F194L on NM_001936.5) | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DRAM2 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSC1 | c.2074T>C p.W692R | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DYSF | c.1823A>C p.D608A | Missense Mutation (SNP) | VAF 239/607 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- EDRF1 | c.3245A>G p.E1082G (on ENST00000356792 / NM_001202438.2; = p.E1048G on NM_015608.2) | Missense Mutation (SNP) | VAF 62/484 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EHD2 | c.1607G>T p.R536L | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- ELAVL4 | c.807dup p.P270Sfs*10 | Frame Shift Ins (INS) | VAF 8/51 reads (16%) | called by mutect2, pindel
- ENPP4 | c.785T>G p.L262R | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- EPS15L1 | c.2603A>C p.Q868P | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ERMARD | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EYA3 | c.1468C>G p.L490V | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM135A | c.895C>G p.L299V (on ENST00000370479 / NM_001351599.1; = p.L282V on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.984); called by muse, varscan2
- FAP | c.995G>C p.C332S | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.487); called by muse, mutect2
- FASTKD5 | c.1616A>G p.Q539R | Missense Mutation (SNP) | VAF 80/263 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- FBXL8 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 48/217 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FCRL5 | c.1283C>A p.S428Y | Missense Mutation (SNP) | VAF 41/216 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FOXD4 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 54/872 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- GABRB3 | c.810T>A p.D270E | Missense Mutation (SNP) | VAF 50/333 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- GH2 | c.629C>A p.S210Y | Missense Mutation (SNP) | VAF 136/570 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- GOLGA2 | c.631A>T p.I211L | Missense Mutation (SNP) | VAF 48/327 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GP5 | c.1421G>T p.G474V | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GPA33 | c.16T>C p.W6R | Missense Mutation (SNP) | VAF 53/258 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- GTPBP3 | c.449A>G p.N150S | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- HDAC4 | c.2704A>T p.M902L | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); called by mutect2, varscan2
- HEPH | c.2204A>G p.Y735C (on ENST00000343002; = p.Y468C on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- HERC2 | c.7793A>T p.D2598V | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ICAM3 | c.1262T>G p.L421R | Missense Mutation (SNP) | VAF 58/339 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ICE1 | c.4259A>G p.K1420R | Missense Mutation (SNP) | VAF 21/289 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); called by muse, mutect2
- INMT | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 27/332 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- INSRR | c.2804T>A p.I935N | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- KCNJ12 | c.892A>G p.I298V | Missense Mutation (SNP) | VAF 27/278 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.727); called by muse, mutect2
- KIF1B | c.349G>A p.G117S | Missense Mutation (SNP) | VAF 77/317 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF26B | c.2531C>A p.P844H | Missense Mutation (SNP) | VAF 12/217 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2
- KMT2D | c.11461C>T p.Q3821* | Nonsense Mutation (SNP) | VAF 24/129 reads (19%) | called by muse, mutect2, varscan2
- LAMA1 | c.952G>T p.V318L | Missense Mutation (SNP) | VAF 84/400 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LRRC4C | c.982G>T p.A328S | Missense Mutation (SNP) | VAF 15/224 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); called by muse, mutect2
- LRRC69 | c.251C>A p.S84Y | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- MBTD1 | c.392A>T p.K131M | Missense Mutation (SNP) | VAF 51/177 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- MIA3 | c.1483G>T p.V495L | Missense Mutation (SNP) | VAF 73/227 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- MROH6 | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MST1R | c.1513C>A p.L505I | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- MTUS2 | c.2540C>A p.A847D | Missense Mutation (SNP) | VAF 25/235 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- MTX1 | c.955-2A>C p.X319_splice | Splice Site (SNP) | VAF 19/103 reads (18%) | called by muse, mutect2, varscan2
- MUC5B | c.11023C>A p.P3675T | Missense Mutation (SNP) | VAF 19/390 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2
- NLRC3 | c.662T>G p.L221W | Missense Mutation (SNP) | VAF 54/282 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- NRXN2 | c.2345G>A p.R782H | Missense Mutation (SNP) | VAF 79/434 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NUDT22 | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OR10AG1 | c.691A>T p.T231S | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR10V1 | c.548C>A p.P183H | Missense Mutation (SNP) | VAF 40/250 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- OR2A7 | c.339_341del p.L114del | In Frame Del (DEL) | VAF 52/430 reads (12%) | called by pindel, varscan2
- OR2L3 | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 91/231 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR52E8 | c.77T>A p.L26Q | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- OR8K1 | c.517T>A p.S173T | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- P2RY8 | c.354C>G p.S118R | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PAPPA | c.4831C>A p.P1611T | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PCDHAC2 | c.1944G>T p.M648I | Missense Mutation (SNP) | VAF 39/360 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDGFB | c.655C>G p.P219A | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- PLA2G7 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 89/441 reads (20%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEKHG4B | c.2443G>T p.A815S (on ENST00000283426; = p.A1171S on NM_052909.5) | Missense Mutation (SNP) | VAF 63/291 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- PNPLA8 | c.1130A>T p.K377M | Missense Mutation (SNP) | VAF 51/223 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- PRAC1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 35/216 reads (16%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRDM7 | c.1308G>A p.M436I | Missense Mutation (SNP) | VAF 74/455 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRTG | c.2513T>A p.V838D | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PTPN3 | c.41A>G p.N14S | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- RAB11FIP1 | c.235T>C p.S79P | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- RAB7A | c.426G>A p.W142* | Nonsense Mutation (SNP) | VAF 171/508 reads (34%) | called by muse, mutect2, varscan2
- RAD51AP2 | c.1927A>C p.M643L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RB1CC1 | c.2912A>G p.E971G | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- RDH13 | c.729C>G p.I243M (on ENST00000415061 / NM_001145971.2; = p.I172M on NM_138412.4) | Missense Mutation (SNP) | VAF 45/228 reads (20%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROCK1 | c.587A>T p.H196L | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEC16B | c.3158G>T p.R1053L | Missense Mutation (SNP) | VAF 41/249 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC5A10 | c.446A>T p.K149M | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC6A5 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); called by muse, mutect2
- SLCO1A2 | c.1804C>A p.L602I | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.153); called by muse, varscan2
- SMTN | c.1991G>T p.S664I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- SMTNL1 | c.378G>C p.E126D | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- SOD2 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 35/115 reads (30%) | called by muse, mutect2
- SSUH2 | c.-85-2A>G | Splice Site (SNP) | VAF 15/84 reads (18%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.509G>T p.R170M | Missense Mutation (SNP) | VAF 27/262 reads (10%) | PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- STYXL2 | c.893G>A p.G298D | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- SVOP | c.824T>C p.I275T | Missense Mutation (SNP) | VAF 50/311 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- TARS3 | c.2303G>C p.R768P | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TBC1D23 | c.1367G>A p.W456* | Nonsense Mutation (SNP) | VAF 38/274 reads (14%) | called by muse, mutect2, varscan2
- TBC1D7 | c.467G>T p.R156L | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- TEX15 | c.5290G>A p.D1764N (on ENST00000256246; = p.D2147N on NM_001350162.2) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TMTC1 | c.2337G>T p.Q779H (on ENST00000539277 / NM_001193451.2; = p.Q671H on NM_175861.3) | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- TNPO1 | c.1985G>A p.G662E | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRGV5 | c.254A>T p.K85M | Missense Mutation (SNP) | VAF 96/370 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRHDE | c.2751A>T p.Q917H | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIM42 | c.762C>A p.C254* | Nonsense Mutation (SNP) | VAF 93/422 reads (22%) | called by muse, mutect2, varscan2
- TRIM47 | c.699C>A p.S233R | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- TTN | c.95417T>C p.I31806T (on ENST00000591111; = p.I24382T on NM_003319.4) | Missense Mutation (SNP) | VAF 15/142 reads (11%) | PolyPhen benign (0.116); called by muse, mutect2
- TUSC3 | c.905C>G p.A302G | Missense Mutation (SNP) | VAF 61/437 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- WDR64 | c.1499A>C p.N500T | Missense Mutation (SNP) | VAF 49/257 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- XDH | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 240/627 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- ZNF648 | c.803_817del p.P268_G273delinsR | In Frame Del (DEL) | VAF 30/123 reads (24%) | called by mutect2, pindel, varscan2
- ZNF804B | c.1835G>A p.G612D | Missense Mutation (SNP) | VAF 35/222 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ZP4 | c.1010C>A p.P337Q | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZP4 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZPBP | c.202T>G p.F68V | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ACTR2 | c.1158A>G p.L386= | Silent (SNP) | VAF 15/123 reads (12%) | catalogued as rs1328064639; called by muse, mutect2
- ANKRD36B | c.1446A>G p.R482= | Silent (SNP) | VAF 35/124 reads (28%) | called by muse, mutect2, varscan2
- ARHGAP10 | c.2292T>C p.P764= | Silent (SNP) | VAF 17/91 reads (19%) | called by muse, mutect2, varscan2
- BAHCC1 | c.2244G>T p.A748= | Silent (SNP) | VAF 37/255 reads (15%) | catalogued as COSV100311257; called by muse, mutect2, varscan2
- BCAN | c.244C>T p.L82= | Silent (SNP) | VAF 36/198 reads (18%) | called by muse, mutect2, varscan2
- C6 | c.1875T>C p.N625= | Silent (SNP) | VAF 14/267 reads (5%) | catalogued as COSV54711643; called by muse, mutect2
- CREB3L1 | c.18A>G p.E6= | Silent (SNP) | VAF 26/135 reads (19%) | called by muse, mutect2, varscan2
- CTNNA2 | c.2205G>A p.L735= | Silent (SNP) | VAF 11/202 reads (5%) | catalogued as COSV58189050; called by muse, mutect2
- CTTNBP2 | c.591C>A p.A197= | Silent (SNP) | VAF 62/346 reads (18%) | called by muse, mutect2, varscan2
- CTXN2 | c.121T>C p.L41= | Silent (SNP) | VAF 83/409 reads (20%) | catalogued as rs565641676; called by muse, mutect2, varscan2
- CUX2 | c.498C>T p.G166= | Silent (SNP) | VAF 42/212 reads (20%) | catalogued as COSV55646760; called by muse, mutect2, varscan2
- CUX2 | c.2673C>T p.Y891= | Silent (SNP) | VAF 16/140 reads (11%) | called by muse, mutect2, varscan2
- CYFIP2 | c.1161C>T p.R387= | Silent (SNP) | VAF 23/100 reads (23%) | catalogued as rs780117749; called by muse, mutect2, varscan2
- DCC | c.1065T>C p.S355= | Silent (SNP) | VAF 57/282 reads (20%) | called by muse, varscan2
- DLG5 | c.4896G>T p.G1632= | Silent (SNP) | VAF 11/234 reads (5%) | catalogued as COSV64950257; called by muse, mutect2
- ENAM | c.1857A>G p.T619= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as rs1333611901; called by muse, mutect2, varscan2
- FAM124A | c.339A>G p.E113= (on ENST00000322475 / NM_001242312.2; = p.E149= on NM_145019.4) | Silent (SNP) | VAF 13/117 reads (11%) | called by muse, mutect2, varscan2
- FBN2 | c.1416G>T p.G472= | Silent (SNP) | VAF 96/311 reads (31%) | called by muse, mutect2, varscan2
- GRK5 | c.673A>C p.R225= | Silent (SNP) | VAF 13/130 reads (10%) | called by muse, mutect2, varscan2
- H2BC9 | c.138G>A p.L46= | Silent (SNP) | VAF 64/382 reads (17%) | catalogued as rs1473395445, COSV55100465; called by muse, mutect2, varscan2
- HELB | c.690A>G p.K230= | Silent (SNP) | VAF 22/153 reads (14%) | called by muse, mutect2, varscan2
- HMCN2 | c.5151A>G p.P1717= | Silent (SNP) | VAF 37/231 reads (16%) | called by muse, mutect2, varscan2
- IFT57 | c.522A>G p.E174= | Silent (SNP) | VAF 17/133 reads (13%) | called by muse, mutect2, varscan2
- IGHV3-30 | c.93C>A p.V31= | Silent (SNP) | VAF 24/418 reads (6%) | called by muse, mutect2
- IL1RAPL1 | c.924G>A p.E308= | Silent (SNP) | VAF 58/166 reads (35%) | called by muse, varscan2
- IQGAP3 | c.2241G>A p.R747= | Silent (SNP) | VAF 24/228 reads (11%) | catalogued as COSV63250235; called by muse, mutect2, varscan2
- KCNC2 | c.633G>C p.L211= | Silent (SNP) | VAF 7/76 reads (9%) | called by muse, mutect2
- KCNQ5 | c.2601C>T p.S867= | Silent (SNP) | VAF 16/448 reads (4%) | called by muse, mutect2
- KIAA0100 | c.2457C>G p.L819= | Silent (SNP) | VAF 61/315 reads (19%) | called by muse, mutect2, varscan2
- LEO1 | c.609G>A p.Q203= | Silent (SNP) | VAF 21/108 reads (19%) | catalogued as rs1290004031; called by muse, mutect2, varscan2
- LILRB1 | c.765C>T p.V255= (on ENST00000427581; = p.V219= on NM_006669.6) | Silent (SNP) | VAF 17/117 reads (15%) | catalogued as COSV61121581; called by muse, varscan2
- LRP1B | c.12183G>T p.L4061= | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as COSV67249150; called by muse, mutect2, varscan2
- MEF2B | c.111G>C p.V37= | Silent (SNP) | VAF 55/346 reads (16%) | called by muse, mutect2, varscan2
- MROH8 | c.1731A>C p.L577= | Silent (SNP) | VAF 72/273 reads (26%) | called by muse, mutect2, varscan2
- MTIF2 | c.249T>G p.S83= | Silent (SNP) | VAF 20/207 reads (10%) | called by muse, mutect2
- MUC5AC | c.15099G>T p.P5033= | Silent (SNP) | VAF 27/162 reads (17%) | catalogued as COSV100611299; called by muse, mutect2, varscan2
- MYH1 | c.4932G>T p.L1644= | Silent (SNP) | VAF 30/146 reads (21%) | called by muse, mutect2, varscan2
- NBEA | c.927A>G p.G309= | Silent (SNP) | VAF 20/192 reads (10%) | catalogued as COSV59762631; called by muse, mutect2, varscan2
- PCDHB5 | c.720C>T p.P240= | Silent (SNP) | VAF 12/216 reads (6%) | catalogued as COSV50647861; called by muse, mutect2
- PTCH1 | c.1893C>A p.T631= | Silent (SNP) | VAF 61/354 reads (17%) | called by muse, mutect2, varscan2
- QPRT | c.759G>T p.L253= | Silent (SNP) | VAF 14/143 reads (10%) | called by muse, mutect2, varscan2
- RELN | c.10122C>T p.I3374= | Silent (SNP) | VAF 91/539 reads (17%) | catalogued as rs767729538, COSV100633836; ClinVar: likely benign; called by muse, mutect2, varscan2
- RETN | c.12C>T p.L4= | Silent (SNP) | VAF 34/235 reads (14%) | called by muse, mutect2, varscan2
- RPS6KC1 | c.231G>A p.L77= | Silent (SNP) | VAF 26/105 reads (25%) | catalogued as COSV65302309; called by muse, mutect2, varscan2
- RYR2 | c.5757G>T p.R1919= | Silent (SNP) | VAF 42/170 reads (25%) | called by muse, mutect2, varscan2
- SEMA6B | c.1140C>T p.A380= | Silent (SNP) | VAF 34/175 reads (19%) | called by muse, mutect2, varscan2
- SHISA9 | c.931C>A p.R311= | Silent (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- SKAP2 | c.9C>A p.T3= | Silent (SNP) | VAF 56/249 reads (22%) | called by muse, mutect2, varscan2
- SLC26A11 | c.312C>T p.P104= | Silent (SNP) | VAF 47/299 reads (16%) | catalogued as rs1398773416; called by muse, mutect2, varscan2
- SOGA3 | c.1692T>C p.Y564= | Silent (SNP) | VAF 24/159 reads (15%) | called by muse, mutect2, varscan2
- TENM4 | c.1026A>T p.A342= | Silent (SNP) | VAF 24/185 reads (13%) | called by muse, mutect2, varscan2
- TMEM121B | c.1150C>T p.L384= | Silent (SNP) | VAF 42/194 reads (22%) | called by muse, mutect2, varscan2
- TNR | c.3069C>T p.A1023= | Silent (SNP) | VAF 35/267 reads (13%) | called by muse, mutect2, varscan2
- TRAV10 | c.258T>A p.T86= | Silent (SNP) | VAF 29/236 reads (12%) | called by muse, mutect2, varscan2
- TRIM24 | c.1155G>T p.R385= | Silent (SNP) | VAF 47/230 reads (20%) | called by muse, mutect2, varscan2
- UNC13A | c.3229C>T p.L1077= | Silent (SNP) | VAF 23/146 reads (16%) | called by muse, mutect2, varscan2
- USH2A | c.3828T>C p.Y1276= | Silent (SNP) | VAF 58/255 reads (23%) | called by muse, mutect2, varscan2
- ZNF835 | c.591C>A p.A197= | Silent (SNP) | VAF 21/86 reads (24%) | called by muse, mutect2, varscan2
- ZSCAN1 | c.576C>T p.A192= | Silent (SNP) | VAF 22/166 reads (13%) | catalogued as rs756008165, COSV56602692, COSV56604494; called by muse, mutect2
- AC004947.2 | chr7:26536841 C>A | 5'Flank (SNP) | VAF 47/213 reads (22%) | called by muse, mutect2, varscan2
- AC091304.1 | n.427C>A | RNA (SNP) | VAF 132/1399 reads (9%) | catalogued as rs1391618073; called by muse, mutect2
- COL1A2 | c.2782-48G>A | Intron (SNP) | VAF 104/371 reads (28%) | called by muse, mutect2, varscan2
- DDX11 | c.638+936G>C | Intron (SNP) | VAF 33/253 reads (13%) | called by muse, mutect2, varscan2
- DLL4 | c.337-21T>C | Intron (SNP) | VAF 11/106 reads (10%) | called by muse, mutect2, varscan2
- DOCK5 | c.4704+68A>T | Intron (SNP) | VAF 21/169 reads (12%) | called by muse, mutect2, varscan2
- GIGYF2 | c.532+4489T>G | Intron (SNP) | VAF 20/203 reads (10%) | called by muse, mutect2, varscan2
- GVINP1 | n.6942G>T | RNA (SNP) | VAF 19/91 reads (21%) | called by muse, mutect2, varscan2
- HKDC1 | c.2373-41C>A | Intron (SNP) | VAF 5/65 reads (8%) | catalogued as rs1329992189; called by muse, mutect2
- HLA-DOA | c.614-13C>A | Intron (SNP) | VAF 23/196 reads (12%) | called by muse, mutect2, varscan2
- HSPA14 | c.377-260T>C | Intron (SNP) | VAF 8/182 reads (4%) | called by muse, mutect2
- IGLV3-22 | c.-9T>A | 5'UTR (SNP) | VAF 22/103 reads (21%) | catalogued as rs1289799775; called by muse, mutect2, varscan2
- IRF9 | c.991+213G>T | Intron (SNP) | VAF 25/186 reads (13%) | called by muse, mutect2, varscan2
- MC3R | c.-52C>A | 5'UTR (SNP) | VAF 70/246 reads (28%) | catalogued as COSV99710383; called by muse, mutect2, varscan2
- MIR124-2 | chr8:64378200 C>A | 5'Flank (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
- MSRA | c.543+17744G>A | Intron (SNP) | VAF 20/208 reads (10%) | called by muse, mutect2
- NOC2LP2 | n.335G>C | RNA (SNP) | VAF 32/473 reads (7%) | called by muse, mutect2
- PDIA3P1 | chr1:147179456 G>C | 3'Flank (SNP) | VAF 30/634 reads (5%) | called by muse, mutect2
- PEG10 | c.*634G>A | 3'UTR (SNP) | VAF 48/238 reads (20%) | called by muse, mutect2, varscan2
- PLP1 | c.697-13C>T | Intron (SNP) | VAF 105/310 reads (34%) | called by muse, mutect2, varscan2
- PPP1R9A | c.2757+5431A>G | Intron (SNP) | VAF 31/239 reads (13%) | called by muse, mutect2, varscan2
- PRRX1 | c.599+3906C>A | Intron (SNP) | VAF 54/271 reads (20%) | catalogued as rs148572157; called by muse, mutect2, varscan2
- RGS6 | c.1369-11892G>A | Intron (SNP) | VAF 30/205 reads (15%) | called by muse, mutect2, varscan2
- SNORD115-25 | chr15:25218613 G>A | 3'Flank (SNP) | VAF 35/228 reads (15%) | called by muse, mutect2, varscan2
- SNX6 | c.429-671G>A | Intron (SNP) | VAF 15/74 reads (20%) | called by muse, mutect2
- SPART | c.-3+4524G>T | Intron (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2, varscan2
- TMEM38B | c.660+937G>C | Intron (SNP) | VAF 17/98 reads (17%) | called by muse, mutect2, varscan2
- WDR70 | c.*57T>G | 3'UTR (SNP) | VAF 10/44 reads (23%) | catalogued as rs944194721; called by muse, mutect2
- WT1 | chr11:32439505 G>T | 5'Flank (SNP) | VAF 90/454 reads (20%) | called by muse, mutect2, varscan2
